Somatic mutation profile of tumor specimen ALCH-B388-TTP1-A (aliquot ALCH-B388-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B388, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 47.7 years (17,411 days).
Specimen ALCH-B388-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c848d06-a9fd-4427-b0a8-945861635b68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B388-NB1-A (Blood Derived Normal), aliquot ALCH-B388-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/621e325f-fa10-4d11-9ec9-a22685db0226

The open-access MAF lists 397 somatic variants for this specimen: 264 protein-altering or splice-affecting, 79 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 79, Nonsense Mutation 22, Intron 19, 5'UTR 12, RNA 9, 3'UTR 7, Frame Shift Del 7, 5'Flank 4, Splice Site 4, 3'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 89/361 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5488C>T p.R1830C (on ENST00000358273 / NM_001042492.3; = p.R1809C on NM_000267.3) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045139, CM077948, CM092072, CM143435, COSV62203168; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 171/418 reads (41%) | catalogued as rs778376925, CD064644, CM981863, CM991149, COSV58820509, COSV58821737, COSV58821906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.518T>A p.V173E | Missense Mutation (SNP) | VAF 100/358 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSM2A | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 85/468 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1478667703; called by muse, mutect2, varscan2
- ACTRT1 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1233235738; called by muse, mutect2, varscan2
- ADGB | c.2995C>A p.P999T | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1319443574; called by muse, mutect2, varscan2
- APPBP2 | c.1610A>G p.H537R | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.692); catalogued as rs753050093; called by muse, mutect2, varscan2
- ARID1A | c.4448G>T p.G1483V | Missense Mutation (SNP) | VAF 141/534 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs768630495; called by muse, mutect2, varscan2
- ATP1B4 | c.1055C>A p.T352N (on ENST00000218008 / NM_001142447.3; = p.T348N on NM_012069.5) | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs1352345097; called by muse, mutect2, varscan2
- B4GALT4 | c.252C>T p.L84= | Splice Region (SNP) | VAF 13/62 reads (21%) | catalogued as rs201212531, COSV100785755; called by muse, mutect2
- BAZ2B | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58596132; called by muse, mutect2, varscan2
- C15orf39 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1187131829; called by muse, mutect2, varscan2
- CCDC136 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs765936662; called by muse, mutect2, varscan2
- CDH9 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs768954953, COSV50261316, COSV50266286; called by muse, mutect2, varscan2
- CDX4 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1391847961; called by muse, mutect2, varscan2
- CELA1 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1468764233; called by muse, mutect2, varscan2
- CEP120 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781329490; called by muse, mutect2, varscan2
- COL11A1 | c.2098G>A p.G700S | Missense Mutation (SNP) | VAF 82/375 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100614689; called by muse, mutect2, varscan2
- COL14A1 | c.1949A>T p.D650V | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV52847720; called by muse, mutect2, varscan2
- COL1A2 | c.4012C>A p.R1338S | Missense Mutation (SNP) | VAF 125/481 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51953052; called by muse, mutect2, varscan2
- CREBBP | c.3187G>T p.E1063* | Nonsense Mutation (SNP) | VAF 121/360 reads (34%) | catalogued as COSV52120852; called by muse, varscan2
- CSF3 | c.324G>C p.L108F | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as COSV99045483; called by muse, mutect2, varscan2
- CSMD3 | c.9916del p.S3306Afs*18 (on ENST00000297405 / NM_001363185.1; = p.S3137Afs*18 on NM_052900.3) | Frame Shift Del (DEL) | VAF 55/492 reads (11%) | catalogued as COSV52278337; called by mutect2*, pindel
- DCTN2 | c.1144C>G p.L382V (on ENST00000548249 / NM_001261413.2; = p.L387V on NM_006400.4) | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs774718356; ClinVar: uncertain significance; called by muse, mutect2
- DENND2A | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as rs747536968; called by muse, varscan2
- DHCR24 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776651391, COSV99054982; called by muse, mutect2, varscan2
- DLG2 | c.156C>G p.I52M (on ENST00000650630 / NM_001351274.2; = p.I15M on NM_001142699.3) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1486299049; called by muse, mutect2
- DNAAF1 | c.1970G>A p.G657D | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1240431038; called by muse, mutect2
- E2F7 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 216/878 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV59740636; called by mutect2, varscan2
- EYS | c.1288G>C p.G430R | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100676079; called by muse, mutect2, varscan2
- EYS | c.929del p.P310Qfs*29 | Frame Shift Del (DEL) | VAF 90/355 reads (25%) | catalogued as COSV99055013; called by mutect2, pindel, varscan2
- FAM83H | c.2987C>A p.P996H | Missense Mutation (SNP) | VAF 170/904 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV62028408; called by muse, mutect2, varscan2
- FTMT | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV58420325; called by muse, mutect2, varscan2
- GFRAL | c.619A>T p.S207C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61231886; called by muse, mutect2, varscan2
- GHSR | c.150C>A p.C50* | Nonsense Mutation (SNP) | VAF 91/424 reads (21%) | catalogued as rs1320610166, COSV53838851; called by muse, mutect2, varscan2
- GNAT3 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs748050219; called by muse, mutect2, varscan2
- HAND2 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs529197560; called by muse, mutect2, varscan2
- HOOK1 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64619863; called by muse, mutect2
- HOXD13 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1435965440, COSV66832416; called by muse, mutect2, varscan2
- IFNA14 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV66516065; called by muse, mutect2, varscan2
- IGHG4 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 210/1528 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs374869082; called by muse, mutect2, varscan2
- IGHMBP2 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV54825749; called by muse, mutect2, varscan2
- INTS6L | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878023; called by muse, mutect2, varscan2
- IQGAP3 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs375628623; called by muse, mutect2
- ITGA11 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs749922264, COSV59876233; called by muse, mutect2, varscan2
- ITGAX | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 48/371 reads (13%) | catalogued as COSV51648998; called by muse, mutect2, varscan2
- IVL | c.1645C>G p.P549A | Missense Mutation (SNP) | VAF 51/1214 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV64216083; called by muse, mutect2
- KCTD9 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55340438; called by muse, varscan2
- KIF2C | c.2174A>G p.Q725R | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); catalogued as rs1168021641; called by muse, mutect2, varscan2
- KLHL1 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs753185463, COSV64775572, COSV64787031; called by muse, mutect2, varscan2
- KLHL10 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 85/537 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs1459130036; called by muse, mutect2, varscan2
- KMT2B | c.6895C>T p.R2299W | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1247091755, COSV55858792; called by muse, mutect2, varscan2
- LRRC15 | c.1410C>A p.N470K | Missense Mutation (SNP) | VAF 156/486 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV61650559; called by muse, mutect2, varscan2
- LRRFIP2 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100368592; called by muse, varscan2
- MEGF10 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs986836353; called by muse, mutect2, varscan2
- MS4A14 | c.1855G>A p.G619R | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV55734777, COSV55738149; called by muse, mutect2, varscan2
- MUC12 | c.1793G>C p.G598A (on ENST00000379442; = p.G455A on NM_001164462.1) | Missense Mutation (SNP) | VAF 124/1167 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs1431765520; called by muse, mutect2, varscan2
- MYADML2 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs760112339; called by muse, mutect2, varscan2
- MYBPC3 | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as CM106112; called by muse, mutect2, varscan2
- NOS1 | c.4262T>C p.I1421T | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as rs1448627745; called by muse, mutect2, varscan2
- NPR2 | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 325/846 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV61309338; called by muse, mutect2, varscan2
- OR13G1 | c.543G>C p.L181F | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62943607; called by muse, varscan2
- OR2A2 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1167150661, COSV68871986; called by muse, mutect2, varscan2
- OR4C11 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100155592, COSV56353774; called by muse, mutect2, varscan2
- PBRM1 | c.1058C>G p.S353* | Nonsense Mutation (SNP) | VAF 83/299 reads (28%) | catalogued as COSV56284997; called by muse, mutect2, varscan2
- PCDH15 | c.4717G>T p.E1573* | Nonsense Mutation (SNP) | VAF 41/674 reads (6%) | catalogued as COSV64740611; called by muse, mutect2
- PFKL | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 101/405 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413393993, COSV62464122; called by muse, mutect2, varscan2
- PLEKHA7 | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV63051683; called by muse, mutect2
- POPDC2 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs748920995; called by muse, mutect2, varscan2
- PRELID2 | c.445G>T p.V149F (on ENST00000334744 / NM_182960.4; = p.V108F on NM_138492.6) | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs769878850; called by muse, varscan2
- PREPL | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1392001224; called by muse, varscan2
- RAB44 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 129/447 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs950811499; called by muse, mutect2, varscan2
- RB1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 54/179 reads (30%) | catalogued as CD941772, CM0910366, COSV57296743, COSV57307114; called by muse, mutect2, varscan2
- RBM34 | c.960A>T p.R320S | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs780778276; called by muse, mutect2
- RBMX2 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 138/704 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV59728633; called by muse, mutect2, varscan2
- RGN | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1431077698; called by muse, mutect2, varscan2
- RNF213 | c.2630G>A p.R877K | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.031); catalogued as COSV60619181; called by muse, mutect2, varscan2
- ROBO4 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.982); catalogued as COSV60626318; called by muse, mutect2, varscan2
- RSPH9 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 45/600 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64664417; called by muse, mutect2
- RUNX1 | c.422G>A p.G141E (on ENST00000344691 / NM_001001890.3; = p.G168E on NM_001754.5) | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55874740, COSV55893340, COSV99038687; called by muse, mutect2, varscan2
- SCN3B | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 53/602 reads (9%) | catalogued as rs1555115604; called by muse, mutect2
- SDCCAG8 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 44/223 reads (20%) | catalogued as COSV100654492; called by muse, mutect2, varscan2
- SIM1 | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV99492728; called by muse, mutect2, varscan2
- SKAP1 | c.887C>A p.A296D | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs973240616; called by muse, mutect2, varscan2
- SLITRK4 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs933600298, COSV62023193; called by muse, mutect2, varscan2
- SOBP | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs757634793, COSV58000409; called by mutect2, varscan2
- SPIN2A | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.974); catalogued as rs750958836, COSV66520510; called by muse, mutect2, varscan2
- STAC2 | c.163C>A p.R55S | Missense Mutation (SNP) | VAF 73/382 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs774231179; called by muse, varscan2
- SYVN1 | c.859A>G p.M287V | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1479070858; called by muse, mutect2, varscan2
- TEKT4 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54629206; called by muse, mutect2, varscan2
- TFDP3 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.206); catalogued as COSV59536932; called by muse, mutect2, varscan2
- TNXB | c.6817G>T p.G2273W (on ENST00000647633; = p.G2026W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 212/1112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64483366; called by muse, mutect2, varscan2
- TRIM56 | c.1525del p.R509Gfs*23 | Frame Shift Del (DEL) | VAF 46/204 reads (23%) | catalogued as COSV60157516; called by mutect2, varscan2
- TTC36 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781863836; called by muse, varscan2
- TTC36 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as rs377476216; called by muse, varscan2
- URB1 | c.2663C>T p.S888L | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs372046735; called by muse, mutect2, varscan2
- USP29 | c.2147A>G p.Y716C | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54146785; called by muse, mutect2, varscan2
- WAS | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 86/863 reads (10%) | catalogued as COSV61920215; called by muse, mutect2
- YLPM1 | c.5422C>T p.P1808S | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV99461752; called by muse, mutect2, varscan2
- ZFHX4 | c.9514C>A p.P3172T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1273442808, COSV51464433; called by muse, mutect2, varscan2
- ZIC4 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 88/446 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV67171447; called by muse, mutect2, varscan2
- ZSCAN25 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV53552968; called by muse, mutect2, varscan2
- ABCA13 | c.12153G>T p.R4051S | Missense Mutation (SNP) | VAF 151/483 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ABCC1 | c.4199G>A p.W1400* | Nonsense Mutation (SNP) | VAF 120/470 reads (26%) | called by muse, mutect2, varscan2
- ABCC9 | c.3843G>T p.K1281N | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ACE2 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 131/363 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS20 | c.1315A>T p.S439C | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2340G>C p.Q780H | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ADCY2 | c.374T>A p.M125K | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2
- ADGRL3 | c.4023C>A p.S1341R (on ENST00000506720 / NM_001322402.2; = p.S1230R on NM_015236.6) | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AIM2 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 87/156 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AMBRA1 | c.3734A>T p.Q1245L (on ENST00000458649 / NM_001367468.1; = p.Q1155L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANO6 | c.1720G>T p.G574C | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSK | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSL | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 33/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASB18 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- AWAT2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by mutect2, varscan2
- BEST2 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BEX2 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BMX | c.1787G>T p.W596L | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPHL | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- CAMK2B | c.988G>C p.A330P | Missense Mutation (SNP) | VAF 162/608 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CCDC112 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD99L2 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 69/269 reads (26%) | called by muse, mutect2, varscan2
- CERCAM | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CHD7 | c.5051-1G>T p.X1684_splice | Splice Site (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- CMTR1 | c.293T>C p.M98T | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CPA4 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CRMP1 | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.9917del p.S3306Tfs*18 (on ENST00000297405 / NM_001363185.1; = p.S3137Tfs*18 on NM_052900.3) | Frame Shift Del (DEL) | VAF 66/460 reads (14%) | called by mutect2, varscan2*
- CYP4A22 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- DENND2C | c.2587C>T p.H863Y (on ENST00000393274 / NM_001256404.2; = p.H806Y on NM_198459.4) | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DHRSX | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 207/954 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ENPP1 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAAH2 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 144/423 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FAM219B | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM234A | c.1647G>C p.Q549H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- FAM83B | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- FNDC1 | c.3100_3108del p.S1034_T1036del | In Frame Del (DEL) | VAF 42/126 reads (33%) | called by mutect2, pindel, varscan2
- FOXP3 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSHB | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRE | c.645C>G p.S215R | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAS7 | c.731+1G>T p.X244_splice (on ENST00000432992 / NM_201433.2; = p.X104_splice on NM_003644.3) | Splice Site (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- GFOD1 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GOLGA8F | c.337G>C p.V113L (on ENST00000526619; = p.V319L on NM_001350920.2) | Missense Mutation (SNP) | VAF 136/1456 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.092); called by muse, varscan2
- GPA33 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 52/636 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- GPATCH8 | c.2212A>T p.S738C | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- GPATCH8 | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPD1L | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 100/339 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR161 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRAP2 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- GRIN2B | c.1826T>A p.L609H | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2AC11 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HCN1 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- HFM1 | c.3814G>A p.D1272N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- HPS6 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.076); called by muse, varscan2
- HSD17B14 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGLV5-37 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 93/383 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGSF9B | c.4185G>T p.K1395N | Missense Mutation (SNP) | VAF 65/597 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- IL18RAP | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- ITPR3 | c.7331-1G>C p.X2444_splice | Splice Site (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- JMY | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- KAT2B | c.2243T>G p.F748C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH7 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 57/233 reads (24%) | called by muse, mutect2, varscan2
- KLHL10 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- KPNA7 | c.707A>C p.D236A | Missense Mutation (SNP) | VAF 112/716 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- L3HYPDH | c.529G>T p.G177* | Nonsense Mutation (SNP) | VAF 48/386 reads (12%) | called by muse, mutect2, varscan2
- LAMA2 | c.2537G>T p.R846M | Missense Mutation (SNP) | VAF 193/527 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA5 | c.8222G>T p.G2741V | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LARS1 | c.3325+3A>T | Splice Region (SNP) | VAF 46/253 reads (18%) | called by muse, mutect2, varscan2
- LRCH2 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRFIP2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- MALT1 | c.1260T>A p.F420L | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MAMLD1 | c.964C>A p.Q322K | Missense Mutation (SNP) | VAF 110/545 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MAP2K3 | c.196A>G p.T66A (on ENST00000342679 / NM_145109.3; = p.T37A on NM_002756.4) | Missense Mutation (SNP) | VAF 83/731 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MECOM | c.2686G>A p.E896K (on ENST00000468789 / NM_001105078.4; = p.E1084K on NM_004991.4) | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- MROH7 | c.3163G>T p.G1055W | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A10 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC16 | c.8798C>G p.P2933R | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYH1 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MYO1D | c.1838T>A p.L613H | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1E | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO9B | c.2725G>T p.D909Y | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NALCN | c.102C>A p.N34K | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.093); called by muse, varscan2
- NAV3 | c.3605A>T p.E1202V | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEB | c.18689C>A p.P6230Q | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP1 | c.2554G>C p.E852Q | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPR3 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRDC | c.2167C>A p.H723N | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, varscan2
- NTNG1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTNG1 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR10Z1 | c.280T>A p.Y94N | Missense Mutation (SNP) | VAF 292/506 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- OR2A5 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4L1 | c.381T>A p.C127* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- ORC2 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OTOA | c.2214G>C p.K738N (on ENST00000286149; = p.K724N on NM_144672.4) | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- P2RY14 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH10 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- PEG3 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- PFKFB4 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PIP4K2A | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PKD1L3 | c.3943T>A p.W1315R | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCB1 | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 140/461 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCH2 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PLPPR4 | c.599C>G p.T200R | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- POM121L12 | c.840G>T p.R280S | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PRAMEF2 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 117/682 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PRDM4 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PROSER2 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- PRR16 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1216G>T p.V406L (on ENST00000421990 / NM_001136042.2; = p.V388L on NM_025267.3) | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- PXDNL | c.4097G>T p.S1366I | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAP1GAP | c.1324A>G p.M442V | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM15 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RBMS1 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- RERE | c.3301G>C p.A1101P | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RHOJ | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ROBO2 | c.3467C>T p.S1156F | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- RSAD2 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 30/226 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.11044C>A p.L3682M | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN7A | c.4586G>T p.R1529M | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- SEMA5A | c.1645T>A p.W549R | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SERPIND1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SFRP5 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 53/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SKA3 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLAMF6 | c.805G>T p.A269S (on ENST00000368057 / NM_001184714.2; = p.A268S on NM_052931.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC23A1 | c.381G>C p.W127C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A12 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SLITRK1 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLTM | c.2363C>T p.S788L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SPAG6 | c.1295T>A p.V432E | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SPATA31A6 | c.3251C>A p.P1084H | Missense Mutation (SNP) | VAF 319/1371 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SPG11 | c.5725G>T p.A1909S | Missense Mutation (SNP) | VAF 103/601 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPO11 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SPTA1 | c.4430G>T p.R1477L | Missense Mutation (SNP) | VAF 573/1090 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- STAG2 | c.2925-2A>T p.X975_splice | Splice Site (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- STIM1 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 125/471 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- STRN | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 51/444 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SULF2 | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 272/1733 reads (16%) | called by muse, mutect2, varscan2
- SYTL4 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TECRL | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TENT5D | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TMEM184B | c.434G>T p.R145I | Missense Mutation (SNP) | VAF 100/385 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TMEM235 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM51 | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 131/615 reads (21%) | called by muse, mutect2, varscan2
- TRIP4 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 113/449 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.54877A>C p.K18293Q (on ENST00000591111; = p.K10869Q on NM_003319.4) | Missense Mutation (SNP) | VAF 45/284 reads (16%) | PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TWNK | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 126/319 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- USH2A | c.14251G>T p.A4751S | Missense Mutation (SNP) | VAF 27/569 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- UTP18 | c.949A>C p.S317R | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- VSIG10L2 | c.1486del p.L496Sfs*100 | Frame Shift Del (DEL) | VAF 24/109 reads (22%) | called by mutect2, pindel, varscan2
- VWA5B1 | c.2854G>T p.E952* (on ENST00000375079; = p.E953* on NM_001039500.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 135/580 reads (23%) | called by muse, mutect2, varscan2
- WDR36 | c.2463G>T p.L821F | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); called by muse, varscan2
- WDR97 | c.287A>T p.H96L | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- YME1L1 | c.1424G>A p.G475E (on ENST00000326799 / NM_139312.3; = p.G418E on NM_014263.4) | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX2 | c.5407del p.Q1803Nfs*3 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- ZNF135 | c.13del p.V5Cfs*10 | Frame Shift Del (DEL) | VAF 147/435 reads (34%) | called by mutect2, pindel, varscan2
- ZNF185 | c.881T>A p.L294H | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF280B | c.689A>T p.Q230L | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF467 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF804B | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 56/214 reads (26%) | called by muse, mutect2, varscan2
- ZSCAN12 | c.1774C>G p.L592V | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABCA12 | c.4824C>G p.L1608= (on ENST00000272895 / NM_173076.3; = p.L1290= on NM_015657.3) | Silent (SNP) | VAF 104/423 reads (25%) | catalogued as rs768291337, COSV55961263; called by muse, mutect2, varscan2
- ABCB4 | c.531A>G p.L177= | Silent (SNP) | VAF 97/372 reads (26%) | called by muse, mutect2, varscan2
- ABCG4 | c.1044T>A p.P348= | Silent (SNP) | VAF 46/175 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.2958G>T p.S986= | Silent (SNP) | VAF 92/448 reads (21%) | catalogued as rs377359204; called by muse, mutect2, varscan2
- ADCY6 | c.1989G>A p.R663= | Silent (SNP) | VAF 80/377 reads (21%) | catalogued as rs1394548737; called by muse, mutect2, varscan2
- ADGRV1 | c.11874A>T p.S3958= | Silent (SNP) | VAF 44/268 reads (16%) | called by muse, mutect2, varscan2
- AHNAK2 | c.8391G>T p.G2797= | Silent (SNP) | VAF 180/843 reads (21%) | catalogued as rs555631969, COSV100318788; called by muse, mutect2, varscan2
- APOBR | c.3165G>A p.P1055= (on ENST00000431282; = p.P1064= on NM_018690.4) | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs746522290; called by muse, mutect2, varscan2
- ARHGEF35 | c.1308G>A p.Q436= | Silent (SNP) | VAF 48/377 reads (13%) | called by muse, mutect2, varscan2
- BTNL9 | c.1164G>A p.V388= | Silent (SNP) | VAF 90/393 reads (23%) | called by muse, mutect2, varscan2
- CNOT9 | c.810C>T p.T270= | Silent (SNP) | VAF 49/426 reads (12%) | catalogued as rs1215019210; called by muse, mutect2, varscan2
- CPN2 | c.411C>T p.P137= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as rs1466303437, COSV100102882; called by muse, mutect2, varscan2
- CPXM1 | c.1908T>C p.L636= | Silent (SNP) | VAF 117/377 reads (31%) | called by muse, mutect2, varscan2
- CREBBP | c.5526C>T p.F1842= | Silent (SNP) | VAF 356/1233 reads (29%) | called by muse, mutect2, varscan2
- CT47B1 | c.75C>A p.A25= | Silent (SNP) | VAF 173/841 reads (21%) | called by muse, mutect2, varscan2
- CYB5R4 | c.423G>A p.E141= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100859425; called by muse, mutect2, varscan2
- CYP4A11 | c.249A>G p.P83= | Silent (SNP) | VAF 47/433 reads (11%) | called by muse, mutect2, varscan2
- DACT1 | c.1683G>T p.P561= | Silent (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- DACT3 | c.1338G>T p.T446= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1187542141; called by muse, mutect2, varscan2
- DCP1A | c.1746A>G p.L582= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as rs781828020, COSV99587966; called by muse, mutect2, varscan2
- DENND2A | c.624G>C p.G208= | Silent (SNP) | VAF 82/297 reads (28%) | called by muse, varscan2
- EFCAB11 | c.315C>A p.T105= | Silent (SNP) | VAF 49/223 reads (22%) | called by muse, mutect2, varscan2
- EVI5L | c.567A>T p.V189= | Silent (SNP) | VAF 105/309 reads (34%) | called by muse, mutect2, varscan2
- FAAH | c.402C>G p.L134= | Silent (SNP) | VAF 122/469 reads (26%) | catalogued as rs1377157258; called by muse, mutect2, varscan2
- FNDC1 | c.4944G>T p.L1648= | Silent (SNP) | VAF 145/393 reads (37%) | called by muse, mutect2, varscan2
- FOXO6 | c.1038G>A p.G346= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- FRMD3 | c.1737C>G p.L579= | Silent (SNP) | VAF 79/164 reads (48%) | called by muse, mutect2, varscan2
- FSTL5 | c.46C>T p.L16= | Silent (SNP) | VAF 18/207 reads (9%) | called by muse, mutect2
- GGCX | c.1773G>A p.T591= | Silent (SNP) | VAF 108/290 reads (37%) | catalogued as rs780870771, COSV52090561; called by muse, mutect2, varscan2
- HELZ2 | c.264C>T p.F88= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1287234487, COSV64410497; called by muse, varscan2
- HFM1 | c.2886G>A p.R962= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs1158510051, COSV54029526; called by muse, varscan2
- HIVEP3 | c.3024A>G p.T1008= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- HYDIN | c.14934A>T p.G4978= | Silent (SNP) | VAF 29/109 reads (27%) | called by muse, mutect2, varscan2
- ITGA8 | c.1086G>T p.L362= | Silent (SNP) | VAF 50/259 reads (19%) | called by muse, mutect2, varscan2
- ITM2A | c.684T>A p.R228= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- KRT73 | c.1383C>T p.S461= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as rs1481015104; called by muse, mutect2
- LAMA5 | c.8223G>T p.G2741= | Silent (SNP) | VAF 26/193 reads (13%) | called by muse, mutect2, varscan2
- MDGA2 | c.51G>A p.R17= | Silent (SNP) | VAF 48/227 reads (21%) | called by muse, mutect2, varscan2
- MFAP4 | c.19C>T p.L7= | Silent (SNP) | VAF 51/234 reads (22%) | catalogued as rs1183461322; called by muse, mutect2, varscan2
- MROH2A | c.3339C>A p.A1113= | Silent (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- MTTP | c.735C>T p.T245= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, varscan2
- MUC12 | c.11868C>T p.F3956= (on ENST00000379442; = p.F3813= on NM_001164462.1) | Silent (SNP) | VAF 403/1517 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.37629G>T p.L12543= | Silent (SNP) | VAF 113/284 reads (40%) | catalogued as COSV67461431; called by muse, mutect2, varscan2
- MYH4 | c.5256C>A p.A1752= | Silent (SNP) | VAF 84/429 reads (20%) | called by muse, mutect2, varscan2
- NEGR1 | c.220C>A p.R74= | Silent (SNP) | VAF 92/343 reads (27%) | catalogued as COSV60864850; called by muse, mutect2, varscan2
- OR2A2 | c.453G>T p.G151= | Silent (SNP) | VAF 73/215 reads (34%) | called by muse, mutect2, varscan2
- OR8I2 | c.240G>A p.K80= | Silent (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- OTC | c.969G>T p.V323= | Silent (SNP) | VAF 65/580 reads (11%) | called by muse, mutect2, varscan2
- PALLD | c.1353C>A p.A451= | Silent (SNP) | VAF 162/777 reads (21%) | called by muse, mutect2, varscan2
- PAPPA | c.1071G>T p.V357= | Silent (SNP) | VAF 154/479 reads (32%) | called by muse, mutect2, varscan2
- PLEC | c.4980C>T p.A1660= (on ENST00000322810 / NM_201380.4; = p.A1550= on NM_000445.5) | Silent (SNP) | VAF 91/335 reads (27%) | catalogued as rs782223095, COSV59639146; called by muse, mutect2, varscan2
- PPP1R3A | c.426C>A p.I142= | Silent (SNP) | VAF 114/592 reads (19%) | catalogued as rs773095577, COSV52876481, COSV99493925; called by muse, mutect2, varscan2
- PPP6R3 | c.66A>T p.V22= | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, varscan2
- PRDM15 | c.3513A>G p.A1171= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- PRKAR1A | c.114G>A p.L38= | Silent (SNP) | VAF 75/346 reads (22%) | called by muse, mutect2, varscan2
- PRSS37 | c.552C>T p.F184= | Silent (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- PSMB11 | c.685C>A p.R229= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as COSV99944366; called by muse, mutect2, varscan2
- PTPN18 | c.1341G>A p.P447= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs754929704; called by muse, mutect2, varscan2
- RASGEF1C | c.304C>A p.R102= | Silent (SNP) | VAF 36/140 reads (26%) | called by muse, mutect2, varscan2
- RBCK1 | c.1101C>T p.F367= (on ENST00000356286 / NM_031229.4; = p.F325= on NM_006462.6) | Silent (SNP) | VAF 110/330 reads (33%) | catalogued as rs762666056; called by muse, mutect2, varscan2
- RGS9 | c.1809C>T p.C603= | Silent (SNP) | VAF 112/479 reads (23%) | catalogued as rs1240986611; called by muse, mutect2, varscan2
- RYR2 | c.228G>T p.R76= | Silent (SNP) | VAF 62/432 reads (14%) | called by muse, mutect2, varscan2
- SCN3A | c.4086C>T p.Y1362= | Silent (SNP) | VAF 48/402 reads (12%) | called by muse, mutect2, varscan2
- SCN7A | c.1617T>A p.I539= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- SH3GL3 | c.21G>A p.K7= | Silent (SNP) | VAF 61/289 reads (21%) | called by muse, mutect2, varscan2
- SHOC1 | c.1342C>T p.L448= | Silent (SNP) | VAF 53/167 reads (32%) | called by muse, mutect2, varscan2
- SKA3 | c.1083T>A p.P361= | Silent (SNP) | VAF 47/313 reads (15%) | called by muse, mutect2, varscan2
- SLC29A3 | c.603G>A p.L201= | Silent (SNP) | VAF 89/519 reads (17%) | catalogued as COSV64386388; called by muse, mutect2, varscan2
- SLC35A2 | c.204C>A p.T68= | Silent (SNP) | VAF 177/523 reads (34%) | called by muse, mutect2, varscan2
- SLC5A3 | c.1083G>A p.V361= | Silent (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- STT3A | c.1734G>T p.V578= | Silent (SNP) | VAF 63/300 reads (21%) | called by muse, mutect2, varscan2
- SYT1 | c.1257C>T p.A419= | Silent (SNP) | VAF 46/377 reads (12%) | catalogued as rs146147511; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBC1D31 | c.66C>T p.A22= | Silent (SNP) | VAF 57/252 reads (23%) | called by muse, mutect2, varscan2
- UBQLN2 | c.1164G>C p.S388= | Silent (SNP) | VAF 171/460 reads (37%) | called by muse, mutect2, varscan2
- WDR12 | c.1203G>C p.L401= | Silent (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- XG | c.468G>A p.L156= | Silent (SNP) | VAF 129/414 reads (31%) | called by muse, mutect2, varscan2
- ZBTB22 | c.1278C>A p.I426= | Silent (SNP) | VAF 58/271 reads (21%) | catalogued as COSV56466604, COSV99802352; called by muse, mutect2, varscan2
- ZNF185 | c.882C>A p.L294= | Silent (SNP) | VAF 50/315 reads (16%) | called by muse, mutect2, varscan2
- ZNF274 | c.444A>G p.Q148= (on ENST00000610905; = p.Q43= on NM_016324.3) | Silent (SNP) | VAF 107/229 reads (47%) | catalogued as rs899098877; called by muse, mutect2, varscan2
- AC005863.1 | n.174C>A | RNA (SNP) | VAF 83/380 reads (22%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-40C>G | 5'UTR (SNP) | VAF 38/399 reads (10%) | catalogued as COSV56032021; called by muse, mutect2
- BLK | c.1030-352C>A | Intron (SNP) | VAF 65/237 reads (27%) | catalogued as rs1314051998; called by muse, mutect2, varscan2
- C7orf77 | n.350C>A | RNA (SNP) | VAF 77/216 reads (36%) | called by muse, varscan2
- CDKN2A | chr9:21967227 C>A | 3'Flank (SNP) | VAF 69/170 reads (41%) | called by muse, mutect2, varscan2
- CEP41 | c.*563G>T | 3'UTR (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- CLBA1 | c.-620A>T | 5'UTR (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- DCHS2 | n.5664G>T | RNA (SNP) | VAF 49/304 reads (16%) | catalogued as rs1281796947, COSV61772464; called by muse, mutect2, varscan2
- DCTN1 | c.2467-45G>T | Intron (SNP) | VAF 64/455 reads (14%) | called by muse, mutect2, varscan2
- DDX4 | c.394+41G>A | Intron (SNP) | VAF 38/204 reads (19%) | called by muse, varscan2
- DNAH14 | c.3052-23000A>G | Intron (SNP) | VAF 33/141 reads (23%) | catalogued as COSV100144687; called by muse, mutect2, varscan2
- DNAJC4 | c.-454G>A | 5'UTR (SNP) | VAF 18/218 reads (8%) | catalogued as COSV99655752; called by muse, mutect2
- DNAJC4 | c.-150G>A | 5'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- EIF3L | c.1576-5del | Intron (DEL) | VAF 45/152 reads (30%) | called by mutect2, pindel, varscan2
- ENPP2 | c.1781-1325G>C | Intron (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- EYS | c.1767-7359G>A | Intron (SNP) | VAF 82/511 reads (16%) | catalogued as rs765095616, COSV65458889; called by muse, mutect2, varscan2
- FAM13C | c.-12C>A | 5'UTR (SNP) | VAF 79/308 reads (26%) | called by muse, mutect2, varscan2
- GALNS | c.244+11G>A | Intron (SNP) | VAF 28/156 reads (18%) | catalogued as rs766408294, COSV51937826; called by muse, mutect2, varscan2
- GLYATL1 | n.144C>A | RNA (SNP) | VAF 159/595 reads (27%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1836+29853C>A | Intron (SNP) | VAF 26/149 reads (17%) | catalogued as rs188490805; called by muse, varscan2
- HDAC8 | c.1111+549G>A | Intron (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- HDAC9 | c.*34_*35del | 3'UTR (DEL) | VAF 28/146 reads (19%) | called by pindel, varscan2
- HSP90AA4P | n.370G>C | RNA (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- IDS | c.418+119C>A | Intron (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- IGKV3D-7 | c.-4C>A | 5'UTR (SNP) | VAF 215/702 reads (31%) | called by muse, mutect2, varscan2
- KCNE5 | c.-27G>T | 5'UTR (SNP) | VAF 84/336 reads (25%) | catalogued as COSV100927722; called by muse, mutect2, varscan2
- KCNE5 | c.-28G>T | 5'UTR (SNP) | VAF 84/332 reads (25%) | called by muse, mutect2, varscan2
- KCNJ16 | c.-108T>C | 5'UTR (SNP) | VAF 28/322 reads (9%) | catalogued as rs1287138558; called by muse, mutect2
- KLF6 | c.*2637C>T | 3'UTR (SNP) | VAF 40/202 reads (20%) | called by muse, mutect2, varscan2
- KRTAP5-2 | c.-2C>A | 5'UTR (SNP) | VAF 62/253 reads (25%) | called by muse, mutect2, varscan2
- LTO1 | c.50+57C>A | Intron (SNP) | VAF 18/120 reads (15%) | catalogued as COSV99654047; called by muse, mutect2, varscan2
- MAP2K1 | c.1023-28G>A | Intron (SNP) | VAF 96/420 reads (23%) | catalogued as rs773882362; called by muse, varscan2
- MIR6511B2 | chr16:15131272 del A | 3'Flank (DEL) | VAF 161/1099 reads (15%) | called by mutect2, pindel, varscan2
- MOGS | c.352+19G>T | Intron (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- MUC19 | n.5793G>T | RNA (SNP) | VAF 87/425 reads (20%) | called by muse, mutect2, varscan2
- NRG3 | c.823+1808G>T | Intron (SNP) | VAF 118/304 reads (39%) | called by muse, mutect2, varscan2
- NRG4 | c.251+2713T>C | Intron (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- NUDT5 | c.*993C>A | 3'UTR (SNP) | VAF 27/139 reads (19%) | catalogued as rs1434079705; called by muse, mutect2, varscan2
- PABPC1P2 | n.843G>A | RNA (SNP) | VAF 35/294 reads (12%) | called by muse, varscan2
- PCDHB6 | chr5:141157627 C>A | 3'Flank (SNP) | VAF 259/1243 reads (21%) | called by muse, mutect2, varscan2
- PELATON | chr20:50275701 G>A | 5'Flank (SNP) | VAF 70/412 reads (17%) | called by muse, varscan2
- PEX19 | c.*1474C>G | 3'UTR (SNP) | VAF 265/429 reads (62%) | called by muse, mutect2, varscan2
- PLPP4 | c.-11C>A | 5'UTR (SNP) | VAF 73/186 reads (39%) | called by muse, mutect2, varscan2
- RAI1 | c.*832A>T | 3'UTR (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- RAN | c.-483G>C | 5'UTR (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- SCUBE1 | c.727+2708G>C | Intron (SNP) | VAF 83/406 reads (20%) | catalogued as COSV99297568; called by muse, varscan2
- SERPINI2 | c.*8G>A | 3'UTR (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- SLC35A2 | chrX:48911869 G>A | 5'Flank (SNP) | VAF 233/676 reads (34%) | called by muse, mutect2, varscan2
- SNORD52 | chr6:31835396 T>G | 5'Flank (SNP) | VAF 154/445 reads (35%) | called by muse, mutect2, varscan2
- SSPOP | n.871C>A | RNA (SNP) | VAF 54/172 reads (31%) | called by muse, mutect2, varscan2
- TPM3 | c.567-30T>C | Intron (SNP) | VAF 41/330 reads (12%) | called by muse, mutect2, varscan2
- TTC36 | c.118+366G>C | Intron (SNP) | VAF 35/140 reads (25%) | called by muse, mutect2, varscan2
- UBE2DNL | n.373G>T | RNA (SNP) | VAF 104/557 reads (19%) | catalogued as rs764206838; called by muse, mutect2, varscan2
- WT1 | chr11:32439611 C>T | 5'Flank (SNP) | VAF 106/404 reads (26%) | called by muse, mutect2, varscan2
